Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3575, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3575-01A (Primary Tumor).

Diagnosis/ diagnoses:

Resected colon and rectosigmoid colon show a rectal carcinoma characterized histologically as a relatively poorly differentiated colorectal adenocarcinoma, extending to within 3 cm of the aboral resection margin and measuring 3.5 cm in diameter at the widest point. Invasive tumor spread within all wall layers of the rectum up to the bordering periproctical fatty tissue. Oral and aboral resection margin is tumor-free as is the resection margin of the soft tissue.

Stage of tumor: pT3; G3

Follow-up report:

Following acetone clearing, preparation of 31 lymph nodes, measuring up to 0.6 cm, in the pericolic fatty tissue bordering the tumor.

These prove to be microscopically tumor-free throughout.

Finally, a tumor stage of pT3 pN0 0/31 L0 V0 R0 is established for the rectal carcinoma diagnosed previously.

Source: NCI Genomic Data Commons file efe837a6-0be4-4f87-ba16-bac8837c6f35 (TCGA-AG-3575.1A19C2A6-8481-4F4B-850E-1AA7DDA778A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).